Somatic mutation profile of tumor specimen TCGA-LN-A5U6-01A (aliquot TCGA-LN-A5U6-01A-11D-A28B-09) from TCGA case TCGA-LN-A5U6, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.3 years (19,840 days).
Specimen TCGA-LN-A5U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 086dec71-d81f-4635-b1f9-bb5bb4ebaa1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A5U6-10A (Blood Derived Normal), aliquot TCGA-LN-A5U6-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab62db61-97f3-4e64-a26e-3145bfce409c

The open-access MAF lists 103 somatic variants for this specimen: 84 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 16, Frame Shift Ins 5, Nonsense Mutation 3, Splice Site 2, Intron 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM17 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147275585; called by muse, mutect2, varscan2
- ADAM22 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs200398630; called by muse, mutect2, varscan2
- ARHGEF11 | c.2909G>A p.G970E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99043446; called by muse, mutect2, varscan2
- CALN1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs1393529730, COSV67945448; called by muse, mutect2, varscan2
- CCDC115 | c.145A>T p.M49L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1281955724; called by muse, mutect2, varscan2
- CCDC136 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as rs570468395, COSV52797381; called by muse, mutect2, varscan2
- COL6A2 | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs372523558; called by muse, mutect2, varscan2
- CYB5B | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1249964574; called by muse, mutect2, varscan2
- EXD2 | c.1002C>A p.D334E (on ENST00000312994 / NM_001193362.1; = p.D209E on NM_018199.3) | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs1408457004; called by muse, mutect2, varscan2
- FREM2 | c.7663G>A p.V2555M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs200997496, COSV54842960; called by muse, mutect2, varscan2
- FRMPD1 | c.1674G>T p.Q558H | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.17); PolyPhen benign (0.135); catalogued as COSV66699115; called by muse, mutect2, varscan2
- H1-1 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55120810; called by muse, mutect2
- IRX5 | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1420165862; called by muse, mutect2, varscan2
- ITCH | c.1529G>A p.R510H (on ENST00000262650 / NM_001257137.3; = p.R469H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765813305, COSV52930911; called by muse, mutect2, varscan2
- ITIH5 | c.941C>A p.T314N | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53664031; called by muse, mutect2, varscan2
- MASP1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs551848961; called by muse, mutect2, varscan2
- MRGPRX1 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1423784289; called by muse, mutect2, varscan2
- MUC7 | c.59G>C p.S20T | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV59216873; called by muse, mutect2, varscan2
- MYO16 | c.2835G>T p.L945F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs762837452, COSV51776982; called by muse, mutect2, varscan2
- NTN4 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs748350808; called by muse, mutect2, varscan2
- NTRK1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs141021604, COSV99061281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10G7 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.068); catalogued as COSV100390080; called by muse, mutect2, varscan2
- OR5D13 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100687016; called by muse, mutect2, varscan2
- PAFAH2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs778716854, COSV100959340; called by muse, mutect2, varscan2
- REG1B | c.333G>T p.W111C | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59308017; called by muse, mutect2
- SCN1A | c.3502G>A p.V1168I (on ENST00000303395 / NM_001202435.3; = p.V1157I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.245); catalogued as rs146374754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SI | c.4043C>T p.T1348M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs192640245; called by muse, mutect2, varscan2
- SLC12A1 | c.3285G>C p.L1095F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258786812; called by muse, mutect2, varscan2
- TNN | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs763519873, COSV53422647; called by muse, mutect2, varscan2
- TRMT12 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV100149178; called by muse, mutect2, varscan2
- ZFP91 | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV60160101; called by muse, mutect2, varscan2
- ZNF775 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs1283608615; called by muse, mutect2, varscan2
- ACSS3 | c.842A>T p.Q281L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- BTG1 | c.78_79insT p.R27Sfs*27 | Frame Shift Ins (INS) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- CCDC93 | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- CD46 | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CD9 | c.2dup p.M1? | Frame Shift Ins (INS) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- CEP350 | c.45G>C p.R15S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CPD | c.2122dup p.S708Ffs*11 | Frame Shift Ins (INS) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- CPVL | c.180G>C p.L60F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- CYB5B | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 54/94 reads (57%) | called by muse, mutect2, varscan2
- CYP2E1 | c.600G>T p.M200I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DGKI | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- DIP2B | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- DNAAF1 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DNTTIP2 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DOCK10 | c.2391C>G p.H797Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DPY19L3 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB3 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ERG | c.1454A>G p.Y485C (on ENST00000398919 / NM_001243428.1; = p.Y461C on NM_004449.4) | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2
- FCN2 | c.785A>C p.Q262P | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FOXN2 | c.795A>C p.K265N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GJA1 | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECA | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- IGKV1D-8 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ITGA6 | c.1027G>C p.E343Q (on ENST00000442250; = p.E304Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 261/568 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLC1 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MDH2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); called by muse, mutect2
- MDH2 | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- MTUS2 | c.2605G>T p.G869W | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MUC17 | c.6344C>A p.A2115D | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MYNN | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- NDST3 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- NKTR | c.114C>G p.N38K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH1 | c.255dup p.A86Cfs*57 | Frame Shift Ins (INS) | VAF 54/97 reads (56%) | called by mutect2, pindel, varscan2
- NTN4 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PCARE | c.3050G>A p.R1017K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.067); called by mutect2, varscan2
- PLXNB2 | c.5216del p.L1739Rfs*32 | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- RBM15 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBM15 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SERGEF | c.1118G>C p.W373S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SH3KBP1 | c.1439_1440insA p.T481Hfs*25 | Frame Shift Ins (INS) | VAF 36/57 reads (63%) | called by mutect2, pindel*, varscan2
- SLK | c.1624A>T p.I542F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SPOCK3 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SYCP1 | c.2921T>A p.L974* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- SYNE1 | c.4645G>A p.G1549R (on ENST00000367255 / NM_182961.4; = p.G1556R on NM_033071.3) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SYNPO2 | c.3253-2A>C p.X1085_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- TP53 | c.189_190del p.P64Qfs*84 | Frame Shift Del (DEL) | VAF 35/51 reads (69%) | called by mutect2, pindel, varscan2
- TRIP12 | c.1226G>C p.R409T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TRRAP | c.9535G>T p.A3179S (on ENST00000359863 / NM_001244580.1; = p.A3150S on NM_003496.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- TTF2 | c.2496+4_2496+15del p.X832_splice | Splice Site (DEL) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- ZEB2 | c.2041G>C p.V681L | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF571 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.1843A>G p.K615E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BCHE | c.748C>T p.L250= | Silent (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- CFAP91 | c.1293T>A p.G431= | Silent (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2, varscan2
- CHPF2 | c.1029G>A p.L343= | Silent (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- FMN2 | c.2673G>T p.L891= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs763905334; called by muse, mutect2, varscan2
- L1CAM | c.1476C>T p.T492= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as rs150805225; called by muse, mutect2, varscan2
- LRCH2 | c.444C>A p.T148= | Silent (SNP) | VAF 33/46 reads (72%) | called by muse, mutect2, varscan2
- MMP11 | c.1185C>T p.P395= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as rs757559270; called by muse, mutect2, varscan2
- MORC1 | c.1470T>G p.L490= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- NAV2 | c.3354C>A p.G1118= (on ENST00000396087 / NM_001244963.2; = p.G1095= on NM_145117.5) | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- PGAM2 | c.246G>T p.V82= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- PRRG2 | c.600G>A p.R200= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- PTCH2 | c.2826G>A p.V942= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1012525955; called by muse, mutect2, varscan2
- RIMKLB | c.480G>A p.T160= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs750088977, COSV55236429; called by muse, mutect2, varscan2
- SLC17A3 | c.1191A>T p.L397= | Silent (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- TGFBR2 | c.624G>A p.K208= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- TLE4 | c.1893C>T p.G631= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- MIR520D | n.9T>G | RNA (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- NR2E1 | c.25+1325C>T | Intron (SNP) | VAF 24/36 reads (67%) | catalogued as rs1230805815; called by muse, mutect2, varscan2
- SLC26A7 | c.1935+228C>A | Intron (SNP) | VAF 27/74 reads (36%) | catalogued as rs775261627, COSV52589558; called by muse, mutect2, varscan2
